Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1M5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1M5-01A (Primary Tumor).

1CA-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: Cervix, NOS C53.9 2/24/11 JW

Name: [REDACTED] Surg. Path. No.: [REDACTED]
Address: [REDACTED] DOB: [REDACTED]
MR No.: [REDACTED] Sex/Race: F UNKNOWN
Service: GYNCOLOGY Location: [REDACTED]
Surgeon: [REDACTED] M.D. Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, KERATINIZING TYPE, 3.6 CM IN GREATEST DIMENSION
- TUMOR INVADDES TO A DEPTH OF 12 MM (TOTAL WALL THICKNESS 16 MM)
- FOCAL LYMPHOVASCULAR SPACE INVASION IDENTIFIED IN AREAS DISTANT FROM MAIN TUMOR MASS
- RESECTION MARGINS ARE FREE OF CARCINOMA
- CARCINOMA IN SITU (CIN III) IS PRESENT ADJACENT TO INVASIVE CARCINOMA
- MILD CHRONIC INFLAMMATION
- SQUAMOUS METAPLASIA

PARAMETRIUM, RADICAL HYSTERECTOMY - NO CARCINOMA IDENTIFIED

VAGINA, RADICAL HYSTERECTOMY

- NO CARCINOMA OR DYSPLASIA IDENTIFIED
- RESECTION MARGINS ARE FREE OF CARCINOMA

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- PROLIFERATIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- EPITHELIAL INCLUSION CYSTS
- FOCAL PARA-OVARIAN ADHESIONS

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- EPITHELIAL INCLUSION CYSTS

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- HYDROSALPINX

LYMPH NODES, LEFT EXTERNAL PELVIC, EXCISION

Diagnostic Discrepancy		

Case Reviewed: 2/24/11

Source: NCI Genomic Data Commons file 8c562858-5a5d-4b35-93b9-26661ee9a240 (TCGA-C5-A1M5.B7A07894-8654-49F3-9583-7AD930443F08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).